Surgical pathology report (de-identified scan), TCGA case TCGA-77-8144, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8144-01A (Primary Tumor).

[page 1 of 2]
Histopathology Report

HISTORY

T2 N0 M0. SCC left lower lobe.

MACROSCOPIC

Five specimens submitted.

1: The specimen is labelled "left lung" and consists of a left lung measuring 150 x 120 x 80 mm. There is a palpable lesion located within the inferior region of the hilum and forming a mass within the lower lobe. This lesion has a subpleural location and measures 55 mm in greatest diameter. This lesion has a 5 mm clearance from the pleura. There is a suture on the pleura where the tumour is closest. The tumour projects into a bronchus. The tumour has a clearance from the bronchial resection margin of 27 mm. Distal to the tumour the lower lobe appears consolidated and contains exudate within bronchitis. The lymph nodes at the hilar resection margin show anthracosilicotic changes. Sectioning the uninvolved lung, particularly of the upper lobe reveals mild centrilobular emphysema. There are no other lesions noted. The tumour has significant necrosis. [1A, bronchial resection margin and vascular resection margin; 1B, tumour plus pleura; 1C-D, tumour plus pleura (sutured pleura); 1E, tumour projecting into bronchus; 1F, tumour plus distal consolidated lung; 1G, tumour plus proximal lung; 1H-I, peribronchial/hilar lymph nodes; 1J, non-neoplastic lung].

2: The specimen is labelled "left lung lymph node No. 5" and consists of a lymph node measuring 5 mm in diameter. [BIT, 2A].

3: The specimen is labelled "lymph node No. 6" and consists of a piece of fatty tissue measuring 40 x 10 x 5 mm. [BIT, 3A].

4: The specimen is labelled "lymph node No. 7" and consists of a piece of fatty tissue measuring 20 x 15 x 4 mm. [Bisected and BIT, 4A].

5: The specimen is labelled "lymph node No. 8" and consists of three fragments of fatty tissue ranging in size from 20-40 mm in diameter. [BIT, 5A].

MICROSCOPIC

1: Sections show a moderately to poorly differentiated squamous cell carcinoma. Cavities are identified within the tumour and these are filled with necrotic keratinous debris. The lesion has an endobronchial component and shows in situ carcinoma of the adjacent bronchial epithelium. It extends widely into the adjacent lung parenchyma and peribronchial soft tissue. Pleural invasion is not identified. There is no blood vessel invasion and no lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial and peribronchial soft tissue resection margin. No lymph node metastases are seen. The uninvolved lung shows evidence of mild centriacinar

[page 2 of 2]
Collected

Histopathology Report

emphysema. Distal to the tumour there is acute and organising obstructive pneumonitis together with bronchiectasis.

2: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

3: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

4: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

5: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

1-5: Left lung and No. 5, No. 6, No. 7 and No. 8 lymph nodes:

1: Moderately to poorly differentiated squamous cell carcinoma; 55 mm in maximal dimension.

2: No blood vessel, lymphatic or perineural invasion present.

3: No pleural invasion identified; clear of bronchial margin.

4: No lymph node metastases.

5: T2N0MX

c.c. Lung Cancer Registry

Source: NCI Genomic Data Commons file d2ae44d4-d204-4947-9d8d-051edce831e1 (TCGA-77-8144.C1A4F906-63EC-4DB6-BA0E-9B22A235CE48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).